Somatic mutation profile of tumor specimen TCGA-FF-8047-01A (aliquot TCGA-FF-8047-01A-11D-2210-10) from TCGA case TCGA-FF-8047, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 38.3 years (13,996 days).
Specimen TCGA-FF-8047-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90fc5a05-bf01-4416-9215-c8fd7a1a380d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-8047-10A (Blood Derived Normal), aliquot TCGA-FF-8047-10A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08913538-5302-40c5-81b7-605f0b7a7508

The open-access MAF lists 122 somatic variants for this specimen: 85 protein-altering or splice-affecting, 30 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 30, Nonsense Mutation 8, 3'UTR 4, Frame Shift Del 3, Frame Shift Ins 3, Translation Start Site 2, 3'Flank 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 49/98 reads (50%) | catalogued as rs761534863; called by muse, mutect2, varscan2
- ABLIM2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 169/352 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs371815593; called by muse, mutect2, varscan2
- AP5Z1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765864595; called by muse, mutect2, varscan2
- ARMC8 | c.1895-1G>A p.X632_splice (on ENST00000469044 / NM_001363941.2; = p.X618_splice on NM_015396.6) | Splice Site (SNP) | VAF 42/141 reads (30%) | catalogued as COSV100509907; called by muse, mutect2, varscan2
- CCDC130 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs764089924; called by muse, mutect2, varscan2
- CEP126 | c.2756C>T p.P919L | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.147); catalogued as rs370774279; called by muse, mutect2, varscan2
- COL3A1 | c.2033G>A p.G678D | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58585687; called by muse, mutect2, varscan2
- DCHS2 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs1560789927; called by muse, mutect2, varscan2
- DSCAML1 | c.2443C>T p.R815C (on ENST00000321322; = p.R755C on NM_020693.4) | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs773368695, COSV58390275; called by muse, mutect2, varscan2
- EPHB2 | c.2560G>A p.A854T (on ENST00000400191 / NM_001309193.2; = p.A855T on NM_004442.7) | Missense Mutation (SNP) | VAF 54/71 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs549199396; called by muse, mutect2, varscan2
- ERBIN | c.2351C>A p.S784* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as rs756397256, COSV52324092, COSV52328966; called by muse, mutect2, varscan2
- FAM47A | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 59/77 reads (77%) | SIFT tolerated (1); PolyPhen possibly damaging (0.526); catalogued as COSV60494083; called by muse, mutect2, varscan2
- FOXP4 | c.1085G>A p.R362Q (on ENST00000307972 / NM_001012426.1; = p.R361Q on NM_138457.3) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV57219967; called by muse, mutect2, varscan2
- GLB1L3 | c.1924G>A p.G642S | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV101345130; called by muse, mutect2, varscan2
- H2BC4 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV58414982; called by muse, mutect2, varscan2
- H4C6 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.786); catalogued as rs1351888970; called by muse, mutect2, varscan2
- HCAR2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs201423596, COSV61026172; called by muse, varscan2
- HOATZ | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1243166216; called by muse, mutect2, varscan2
- IGLC3 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 121/203 reads (60%) | PolyPhen benign (0.015); catalogued as rs545905935; called by mutect2, varscan2
- IGLV3-1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as rs373811509; called by muse, varscan2
- IGLV3-10 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs572588135; called by muse, varscan2
- IL37 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs370690543; called by muse, mutect2, varscan2
- KLHL6 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 90/258 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as COSV104418673; called by muse, mutect2, varscan2
- LIPM | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as rs756271856; called by muse, mutect2, varscan2
- LNPEP | c.434dup p.N145Kfs*34 | Frame Shift Ins (INS) | VAF 49/142 reads (35%) | catalogued as rs748712732; called by mutect2, varscan2
- MAGEL2 | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV58566571; called by muse, mutect2, varscan2
- MAP2K3 | c.774G>A p.M258I (on ENST00000342679 / NM_145109.3; = p.M229I on NM_002756.4) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV100384611; called by muse, mutect2, varscan2
- MMP15 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54679373; called by muse, mutect2, varscan2
- MPP7 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs758713609, COSV61732342; called by muse, mutect2, varscan2
- NEB | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371710158, COSV51372626; called by muse, mutect2, varscan2
- NFKBIE | c.759_762del p.Y254Sfs*13 (on ENST00000275015; = p.Y115Sfs*13 on NM_004556.3) | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs755160004; called by mutect2, pindel
- OR4D1 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52124639; called by muse, mutect2, varscan2
- OTOP2 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs374632139; called by muse, mutect2, varscan2
- PICALM | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100707922, COSV100708295; called by muse, mutect2
- PIWIL1 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99806692; called by muse, mutect2, varscan2
- PTN | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 120/252 reads (48%) | catalogued as rs755896401, COSV61965337; called by muse, mutect2, varscan2
- RBM42 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as COSV52898529, COSV99387254; called by muse, mutect2
- SLC27A5 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs751110550, COSV54018177, COSV54020677; called by muse, mutect2, varscan2
- SNED1 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs750587424, COSV104404638; called by muse, mutect2, varscan2
- SPAG17 | c.3821C>T p.T1274M | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs756839531, COSV60457990; called by muse, mutect2, varscan2
- SPINK5 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV56254748; called by muse, mutect2, varscan2
- STAG2 | c.857A>T p.N286I | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99495570; called by muse, mutect2
- TAOK1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs762696676; called by muse, mutect2, varscan2
- TDRD6 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1038506133, COSV60175230; called by muse, mutect2, varscan2
- TNFRSF14 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 64/68 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs753268654, COSV63187325, COSV63188679, COSV63188708; called by muse, mutect2, varscan2
- UBR5 | c.8144G>A p.W2715* | Nonsense Mutation (SNP) | VAF 37/70 reads (53%) | catalogued as COSV55282607; called by muse, mutect2, varscan2
- USP6 | c.2269C>G p.L757V | Missense Mutation (SNP) | VAF 160/421 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.908); catalogued as COSV100005048; called by muse, mutect2, varscan2
- ZNF644 | c.871del p.R291Efs*7 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | catalogued as rs749473342; called by mutect2, varscan2
- ABCA3 | c.5103G>T p.E1701D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP28 | c.1349T>A p.M450K (on ENST00000383472 / NM_001366230.1; = p.M291K on NM_001010000.3) | Missense Mutation (SNP) | VAF 76/92 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- BCL3 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, varscan2
- CACTIN | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CBWD6 | c.451T>A p.W151R | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CLASP1 | c.3638A>G p.D1213G | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL17A1 | c.2876A>G p.Q959R | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- COL6A1 | c.2897G>A p.G966D | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CSK | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 32/72 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- CSMD3 | c.727G>T p.G243* | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- CTNND2 | c.81G>T p.K27N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHA7 | c.597A>C p.K199N | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ESYT3 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 135/228 reads (59%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, varscan2
- EXOC3L1 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCM | c.1384A>T p.K462* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- IGKV1D-13 | c.199A>C p.K67Q | Missense Mutation (SNP) | VAF 104/351 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.387); called by muse, varscan2
- KMT2A | c.6209A>G p.K2070R | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KMT2D | c.14540G>T p.G4847V | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LDOC1 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MPDZ | c.3541G>A p.V1181M | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- MTMR1 | c.475A>C p.K159Q | Missense Mutation (SNP) | VAF 84/111 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, varscan2
- MTMR10 | c.401T>G p.L134* | Nonsense Mutation (SNP) | VAF 65/115 reads (57%) | called by muse, mutect2, varscan2
- NEK1 | c.2042A>T p.K681I | Missense Mutation (SNP) | VAF 88/104 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NFKBIE | c.502dup p.L168Pfs*42 (on ENST00000275015; = p.L29Pfs*42 on NM_004556.3) | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- NUTM1 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52R1 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PKN3 | c.1289A>G p.E430G | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLEKHO2 | c.1063C>G p.P355A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAD51AP1 | c.1042A>G p.N348D (on ENST00000228843 / NM_001130862.2; = p.N331D on NM_006479.5) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SERPINC1 | c.715A>C p.I239L | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SETD1B | c.1466del p.P489Lfs*19 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | called by pindel, varscan2*
- STXBP5 | c.856G>T p.G286W | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.13846G>A p.E4616K (on ENST00000367255 / NM_182961.4; = p.E4545K on NM_033071.3) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VIT | c.191C>A p.A64E | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- WDR13 | c.1264dup p.A422Gfs*8 | Frame Shift Ins (INS) | VAF 27/45 reads (60%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.7574A>T p.H2525L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- ZNF555 | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGAP1 | c.222G>A p.K74= | Silent (SNP) | VAF 96/237 reads (41%) | called by muse, mutect2, varscan2
- BCL7C | c.36C>T p.S12= | Silent (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- CCDC185 | c.588C>T p.P196= | Silent (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- CHAD | c.882C>T p.T294= | Silent (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- DNAH1 | c.5580C>T p.L1860= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as rs775222234; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBN1 | c.3456G>A p.A1152= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as rs777442762, COSV100353920; called by muse, mutect2, varscan2
- HSPA12A | c.144C>T p.N48= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as rs782011441; called by muse, mutect2, varscan2
- IGLL5 | c.45G>A p.E15= | Silent (SNP) | VAF 57/65 reads (88%) | catalogued as rs544778929, COSV73248964, COSV73249402; called by muse, varscan2
- IGLV3-1 | c.108A>C p.T36= | Silent (SNP) | VAF 26/33 reads (79%) | catalogued as rs374263393; called by muse, varscan2
- IGLV3-10 | c.345T>C p.H115= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs367977093; called by muse, mutect2, varscan2
- KCNC1 | c.1029C>T p.N343= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs755107336, COSV99789841; called by muse, mutect2, varscan2
- KLHL29 | c.72C>T p.N24= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs946404086, COSV72085449; called by muse, mutect2, varscan2
- KRT24 | c.393C>A p.G131= | Silent (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- LIMD2 | c.339G>A p.E113= | Silent (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- LIMD2 | c.219G>A p.K73= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs755717333; called by muse, mutect2, varscan2
- LRRN3 | c.1293T>C p.N431= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- MANEA | c.1095C>T p.I365= | Silent (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- MYC | c.312G>A p.E104= (on ENST00000377970; = p.E119= on NM_002467.6) | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV104388509; called by muse, mutect2, varscan2
- NHSL1 | c.4185C>T p.G1395= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs1367989647; called by muse, mutect2, varscan2
- ONECUT2 | c.402C>T p.S134= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- OR4C6 | c.792C>A p.P264= | Silent (SNP) | VAF 61/137 reads (45%) | catalogued as COSV58603399, COSV58604095; called by muse, mutect2, varscan2
- PHEX | c.1026C>T p.R342= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as rs746847960, COSV101040076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNB2 | c.5382C>T p.L1794= | Silent (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- POLR1F | c.627A>G p.E209= | Silent (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- PSME3 | c.15G>A p.L5= | Silent (SNP) | VAF 64/145 reads (44%) | catalogued as rs747536050; called by muse, mutect2, varscan2
- RTL9 | c.3813G>A p.R1271= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV101511813; called by muse, mutect2
- SPPL2C | c.939G>A p.P313= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs150961436; called by muse, mutect2
- TAS1R2 | c.1314C>T p.F438= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as rs146531311, COSV64745169, COSV64746686; called by muse, mutect2, varscan2
- TM9SF2 | c.1446G>C p.V482= | Silent (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2
- ZP3 | c.366C>T p.P122= (on ENST00000394857 / NM_001110354.2; = p.P71= on NM_007155.6) | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as rs774866065; called by muse, mutect2, varscan2
- B3GALT1 | c.*7T>A | 3'UTR (SNP) | VAF 38/78 reads (49%) | catalogued as COSV100003130; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152447123 A>G | 3'Flank (SNP) | VAF 46/104 reads (44%) | called by mutect2, varscan2
- H2AC6 | c.*66C>T | 3'UTR (SNP) | VAF 33/70 reads (47%) | catalogued as rs773360772, COSV100019814; called by muse, mutect2, varscan2
- MIR600 | chr9:123110701 A>C | 3'Flank (SNP) | VAF 70/131 reads (53%) | called by muse, mutect2, varscan2
- NANOS1 | c.*581A>C | 3'UTR (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100403986; called by muse, varscan2
- NANOS1 | c.*648A>C | 3'UTR (SNP) | VAF 50/118 reads (42%) | catalogued as COSV100403987; called by muse, varscan2
- PRRX1 | c.599+3876A>G | Intron (SNP) | VAF 98/341 reads (29%) | called by muse, mutect2, varscan2
